Gene-level copy-number profile of tumor specimen MP2PRT-PAVPBN-TBP1-A from MP2PRT case MP2PRT-PAVPBN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,972 days).
Specimen MP2PRT-PAVPBN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f9b41668-30cd-4e9d-a702-d16186380c07.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVPBN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/559dd718-a70e-4039-9bad-ad00e05e3bec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 278; copy number 1: 2,065; copy number 2: 54,677; copy number 3: 1,377.

Homozygous deletions (total copy number 0; autosomes only): 278 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,254,015, 40 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:90,114,838–90,122,564, 2 genes (within-gene range 0–2): IGKV3D-15, IGKV2D-14.
- chr3:183,253,253–183,298,504, 2 genes (within-gene range 0–1): B3GNT5, RNA5SP151.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–2): TRGC1.
- chr7:38,273,587–38,311,808, 6 genes (within-gene range 0–2): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:112,486,827–112,718,149, 3 genes (within-gene range 0–2): KIAA1958, AL445187.1, INIP.
- chr14:22,155,079–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,538,344, 132 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,219,647–22,245,515, 4 genes: IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
